MMRF case MMRF_1284 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/36df6041-8d49-4c46-88cc-ee1684bd78f7

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 59 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 59.8 years (21,830 days); ISS stage: II; Days to last known disease status: 1,563 days (4.3 years); Days to last follow up: 1,563 days (4.3 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 43 days.
   Treatment given: Therapeutic agents: Bortezomib + Cyclophosphamide + Dexamethasone + Other; Regimen or line of therapy: First line of therapy; Days to treatment start: 71 days; Days to treatment end: 74 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 107 days; Days to treatment end: 107 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 108 days; Days to treatment end: 108 days.
   Treatment given: Therapeutic agents: Pomalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 240 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -2 (ECOG 0): M Protein 5.97 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.12 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.11 mg/dL; Immunoglobulin G 70.1 g/L; Immunoglobulin A 0.25 g/L; Immunoglobulin M 0.09 g/L; Beta 2 Microglobulin 2.33 µg/mL; Lactate Dehydrogenase 2.35 µkat/L; Hemoglobin 5.7 mmol/L; Leukocytes 5.4 ×10⁹/L; Absolute Neutrophil 4.32 ×10⁹/L; Platelets 338 ×10⁹/L; Creatinine 87.5 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.38 mmol/L; Albumin 27 g/L; Total Protein 11.3 g/dL; Glucose 5.06 mmol/L; C-Reactive Protein 3.96 mg/dL.
- Day 82 (ECOG 2): M Protein 4.21 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.12 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.05 mg/dL; Immunoglobulin G 50.5 g/L; Immunoglobulin A 0.0667 g/L; Immunoglobulin M 0.0417 g/L; Beta 2 Microglobulin 2.45 µg/mL; Hemoglobin 5.95 mmol/L; Leukocytes 6.5 ×10⁹/L; Absolute Neutrophil 4.87 ×10⁹/L; Platelets 482 ×10⁹/L; Creatinine 77.8 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.23 mmol/L; Albumin 30 g/L; Total Protein 9.9 g/dL; Glucose 5.06 mmol/L.
- Day 206: M Protein 1.19 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.26 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.73 mg/dL; Immunoglobulin G 22.6 g/L; Immunoglobulin A 0.27 g/L; Immunoglobulin M 0.47 g/L; Beta 2 Microglobulin 2.1 µg/mL; Lactate Dehydrogenase 2.72 µkat/L; Hemoglobin 6.57 mmol/L; Leukocytes 4.2 ×10⁹/L; Absolute Neutrophil 1.89 ×10⁹/L; Platelets 235 ×10⁹/L; Creatinine 74.3 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.38 mmol/L; Albumin 39 g/L; Total Protein 8 g/dL; Glucose 5.61 mmol/L.
- Day 261 (ECOG 1): M Protein 1.23 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.11 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.96 mg/dL; Immunoglobulin G 22.5 g/L; Immunoglobulin A 0.35 g/L; Immunoglobulin M 0.58 g/L; Beta 2 Microglobulin 2.92 µg/mL; Lactate Dehydrogenase 2.7 µkat/L; Hemoglobin 6.51 mmol/L; Leukocytes 3.8 ×10⁹/L; Absolute Neutrophil 1.71 ×10⁹/L; Platelets 214 ×10⁹/L; Creatinine 80.4 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.2 mmol/L; Albumin 40 g/L; Total Protein 8.3 g/dL; Glucose 5.39 mmol/L.
- Day 354: M Protein 1.19 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.23 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.74 mg/dL; Immunoglobulin G 21.7 g/L; Immunoglobulin A 0.44 g/L; Immunoglobulin M 0.37 g/L; Beta 2 Microglobulin 2.01 µg/mL; Hemoglobin 7.81 mmol/L; Leukocytes 6.2 ×10⁹/L; Absolute Neutrophil 4.46 ×10⁹/L; Platelets 214 ×10⁹/L; Creatinine 80.4 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.18 mmol/L; Albumin 35 g/L; Total Protein 8.5 g/dL; Glucose 5.83 mmol/L.
- Day 436 (ECOG 0): M Protein 1.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.83 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.17 mg/dL; Immunoglobulin G 23.4 g/L; Immunoglobulin A 0.77 g/L; Immunoglobulin M 0.98 g/L; Beta 2 Microglobulin 2.05 µg/mL; Lactate Dehydrogenase 2.32 µkat/L; Hemoglobin 7.81 mmol/L; Leukocytes 3.6 ×10⁹/L; Absolute Neutrophil 1.74 ×10⁹/L; Platelets 177 ×10⁹/L; Creatinine 74.3 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.3 mmol/L; Albumin 40 g/L; Total Protein 8.4 g/dL; Glucose 5.28 mmol/L.
- Day 534 (ECOG 1): M Protein 0.97 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.25 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.91 mg/dL; Immunoglobulin G 20.8 g/L; Immunoglobulin A 0.84 g/L; Immunoglobulin M 0.72 g/L; Beta 2 Microglobulin 2.34 µg/mL; Lactate Dehydrogenase 2.12 µkat/L; Hemoglobin 8.06 mmol/L; Leukocytes 2.6 ×10⁹/L; Absolute Neutrophil 0.8 ×10⁹/L; Platelets 147 ×10⁹/L; Creatinine 69.8 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.28 mmol/L; Albumin 38 g/L; Total Protein 7.6 g/dL; Glucose 5.78 mmol/L.
- Day 625 (ECOG 0): M Protein 0.92 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.41 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.83 mg/dL; Immunoglobulin G 20.4 g/L; Immunoglobulin A 0.75 g/L; Immunoglobulin M 0.46 g/L; Beta 2 Microglobulin 2.12 µg/mL; Lactate Dehydrogenase 2.33 µkat/L; Hemoglobin 8.25 mmol/L; Leukocytes 2.9 ×10⁹/L; Absolute Neutrophil 1.76 ×10⁹/L; Platelets 232 ×10⁹/L; Creatinine 76 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.35 mmol/L; Albumin 41 g/L; Total Protein 8.1 g/dL; Glucose 4.9 mmol/L.
- Day 737 (ECOG 0): M Protein 0.96 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.46 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.83 mg/dL; Immunoglobulin G 18.2 g/L; Immunoglobulin A 0.81 g/L; Immunoglobulin M 0.5 g/L; Beta 2 Microglobulin 2.64 µg/mL; Lactate Dehydrogenase 2.18 µkat/L; Hemoglobin 8 mmol/L; Leukocytes 2.8 ×10⁹/L; Platelets 213 ×10⁹/L; Creatinine 82.2 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.25 mmol/L; Albumin 37 g/L; Total Protein 8.1 g/dL; Glucose 8.31 mmol/L.
- Day 821 (ECOG 0): M Protein 0.86 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.86 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.74 mg/dL; Immunoglobulin G 18.4 g/L; Immunoglobulin A 0.95 g/L; Immunoglobulin M 0.34 g/L; Beta 2 Microglobulin 2.41 µg/mL; Lactate Dehydrogenase 2.1 µkat/L; Hemoglobin 8.37 mmol/L; Leukocytes 2.3 ×10⁹/L; Absolute Neutrophil 1.05 ×10⁹/L; Platelets 234 ×10⁹/L; Creatinine 76 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.38 mmol/L; Albumin 40 g/L; Total Protein 8.3 g/dL; Glucose 5.45 mmol/L.
- Day 905 (ECOG 0): M Protein 0.79 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.4 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.84 mg/dL; Immunoglobulin G 20.4 g/L; Immunoglobulin A 1.03 g/L; Immunoglobulin M 0.32 g/L; Beta 2 Microglobulin 2.44 µg/mL; Lactate Dehydrogenase 2.22 µkat/L; Hemoglobin 7.56 mmol/L; Leukocytes 1.8 ×10⁹/L; Absolute Neutrophil 0.8 ×10⁹/L; Platelets 212 ×10⁹/L; Creatinine 75.1 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.35 mmol/L; Albumin 39 g/L; Total Protein 8.2 g/dL; Glucose 5.56 mmol/L.
- Day 996 (ECOG 0): M Protein 0.78 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.18 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.84 mg/dL; Immunoglobulin G 17.8 g/L; Immunoglobulin A 1.16 g/L; Immunoglobulin M 0.37 g/L; Beta 2 Microglobulin 2.15 µg/mL; Lactate Dehydrogenase 1.93 µkat/L; Hemoglobin 8.06 mmol/L; Leukocytes 2.2 ×10⁹/L; Absolute Neutrophil 0.91 ×10⁹/L; Platelets 199 ×10⁹/L; Creatinine 91.9 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.38 mmol/L; Albumin 40 g/L; Total Protein 8.3 g/dL; Glucose 5.83 mmol/L.
- Day 1,087 (ECOG 0): M Protein 0.67 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.81 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.3 mg/dL; Immunoglobulin G 16.7 g/L; Immunoglobulin A 1.13 g/L; Immunoglobulin M 0.4 g/L; Beta 2 Microglobulin 1.94 µg/mL; Lactate Dehydrogenase 2.27 µkat/L; Hemoglobin 8.37 mmol/L; Leukocytes 3.1 ×10⁹/L; Absolute Neutrophil 1.72 ×10⁹/L; Platelets 153 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.3 mmol/L; Albumin 38 g/L; Total Protein 7.8 g/dL; Glucose 5.83 mmol/L.
- Day 1,143 (ECOG 0): M Protein 0.61 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.68 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.46 mg/dL; Immunoglobulin G 17.2 g/L; Immunoglobulin A 1.15 g/L; Immunoglobulin M 0.36 g/L; Beta 2 Microglobulin 2.26 µg/mL; Lactate Dehydrogenase 2.4 µkat/L; Hemoglobin 8.06 mmol/L; Leukocytes 2.9 ×10⁹/L; Absolute Neutrophil 1.5 ×10⁹/L; Platelets 223 ×10⁹/L; Creatinine 77.8 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.35 mmol/L; Albumin 40 g/L; Total Protein 8.3 g/dL; Glucose 8.86 mmol/L.
- Day 1,227 (ECOG 0): M Protein 0.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.53 mg/dL; Immunoglobulin G 16.3 g/L; Immunoglobulin A 1.31 g/L; Immunoglobulin M 0.39 g/L; Beta 2 Microglobulin 1.94 µg/mL; Lactate Dehydrogenase 2.02 µkat/L; Hemoglobin 8.12 mmol/L; Leukocytes 3 ×10⁹/L; Absolute Neutrophil 1.68 ×10⁹/L; Platelets 223 ×10⁹/L; Creatinine 78.7 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.35 mmol/L; Albumin 39 g/L; Total Protein 8.1 g/dL; Glucose 5.06 mmol/L.
- Day 1,339 (ECOG 0): M Protein 0.46 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.79 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.24 mg/dL; Immunoglobulin G 14.6 g/L; Immunoglobulin A 1.49 g/L; Immunoglobulin M 0.34 g/L; Beta 2 Microglobulin 1.81 µg/mL; Lactate Dehydrogenase 2.42 µkat/L; Hemoglobin 7.87 mmol/L; Leukocytes 3.1 ×10⁹/L; Absolute Neutrophil 1.91 ×10⁹/L; Platelets 211 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.43 mmol/L; Albumin 41 g/L; Total Protein 7.6 g/dL; Glucose 5.39 mmol/L.
- Day 1,451 (ECOG 0): M Protein 0.45 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.23 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.23 mg/dL; Immunoglobulin G 13.5 g/L; Immunoglobulin A 1.71 g/L; Immunoglobulin M 0.38 g/L; Lactate Dehydrogenase 2.17 µkat/L; Hemoglobin 8.18 mmol/L; Leukocytes 3 ×10⁹/L; Absolute Neutrophil 1.6 ×10⁹/L; Platelets 228 ×10⁹/L; Creatinine 69 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.45 mmol/L; Albumin 42 g/L; Total Protein 7.6 g/dL; Glucose 4.9 mmol/L.
- Day 1,563 (ECOG 0): M Protein 0.36 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.25 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.36 mg/dL; Immunoglobulin G 13.9 g/L; Immunoglobulin A 1.91 g/L; Immunoglobulin M 0.38 g/L; Beta 2 Microglobulin 1.68 µg/mL; Lactate Dehydrogenase 2.35 µkat/L; Hemoglobin 8.06 mmol/L; Leukocytes 2.6 ×10⁹/L; Absolute Neutrophil 1.53 ×10⁹/L; Platelets 242 ×10⁹/L; Creatinine 74.3 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.43 mmol/L; Albumin 41 g/L; Total Protein 7.8 g/dL; Glucose 5.72 mmol/L.

Other clinical attributes
- Day -2: Weight: 77 kg; Height: 173 cm.

Biospecimens (3 samples)
- Sample MMRF_1284_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -2 days.
- Sample MMRF_1284_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -2 days.
- Sample MMRF_1284_2_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Days to sample procurement: 206 days.
